Surgical pathology report (de-identified scan), TCGA case TCGA-WC-A888, project TCGA-UVM (Uveal Melanoma), tissue source site MD Anderson, specimen TCGA-WC-A888-01A (Primary Tumor).

Accession:

Specimen Date/Time:

DIAGNOSIS

(A) RIGHT GLOBE:

(1-30%)

(61-90%)

CHOROIDAL MELANOMA, MIXED SPINDLED AND EPITHELIOID CELL TYPES

15 mm base x 11mm height

Scleral invasion: absent

Vortex veins: negative for tumor

Optic nerve: negative for tumor

See comment.

ICD 0-3

Melanoma, epithelioid, spindle
cell mixed 8770/3

Site B Choroid C69.3

9/11/14

COMMENT

Mitoses are than 1 per 10 hpf.

PATHOLOGIC STAGE BASED ON PATHOLOGY MATERIAL REVIEWED IN THIS ACCESSION

Primary tumor: pT3
Regional lymph nodes: pNX
Distant metastases: pMX

(American Joint Committee on Cancer, 7th Edition, 2010)

GROSS DESCRIPTION

(A) RIGHT GLOBE – An enucleation specimen (22 mm anterior to posterior, 23 mm medial to lateral, and 23 mm superior to inferior), has an attached 2 cm optic nerve. The skull surface is unremarkable. The cornea is clear and formed by a 10x11-brown iris which has an eccentric 4 mm pupil. A shadow is present in the temporal aspect approximately 15 x 15 mm base 7 mm from the optic nerve and 5 mm from the limbus, this corresponds to a brown tumor centered on the choroid with an 1' height. The eye is opened fresh for protocol harvest. The vitreous is watery. The choroid appears intact beneath the tumor

SECTION CODE: A1, vortex veins; A2, optic nerve with margin en face; A3-A5, trisection of globe (A5 with pupil or nerve section).

BIOMARKER TESTING

Primary Tumor Block: A4

CLINICAL HISTORY

None given.

SNOMED CODES

T-AA000, M-87203

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

These tests have no

-----END OF REPORT-----

Case is Clinic	DISMISSED	DISQUALIFIED

Source: NCI Genomic Data Commons file 54ce6af0-3045-4768-98a6-a96c22702934 (TCGA-WC-A888.513B512E-E9DF-4628-BD36-CADBF3725D9A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).